Somatic mutation profile of tumor specimen C3L-01978-01 (aliquot CPT0125620007) from CPTAC case C3L-01978, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 57.4 years (20,952 days).
Specimen C3L-01978-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fde7b568-5ef7-4fef-b666-69e043355156.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01978-31 (Blood Derived Normal), aliquot CPT0124260002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/16cd93d7-c7cd-4122-a329-6704d979c4b8

The open-access MAF lists 55 somatic variants for this specimen: 39 protein-altering or splice-affecting, 9 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 9, Intron 6, Frame Shift Del 2, Nonsense Mutation 2, Splice Region 1, 3'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KCNN4 | c.1055G>A p.R352H | Missense Mutation (SNP) | VAF 27/208 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.812); catalogued as rs774455945, CM158891, COSV53457124; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAM2 | c.1331T>C p.M444T | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs750464648; called by muse, mutect2, varscan2
- ARMC9 | c.1462C>T p.L488F | Missense Mutation (SNP) | VAF 24/159 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1217845207; called by muse, mutect2, varscan2
- BCHE | c.490G>A p.V164I | Missense Mutation (SNP) | VAF 27/160 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.264); catalogued as rs758223727; called by muse, mutect2, varscan2
- CD46 | c.751A>G p.T251A | Missense Mutation (SNP) | VAF 40/222 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.05); catalogued as rs1263127363; called by muse, mutect2, varscan2
- CELSR1 | c.3527T>C p.M1176T | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.235); catalogued as rs1004806012; called by muse, varscan2
- CRACDL | c.-9G>A | Splice Region (SNP) | VAF 19/144 reads (13%) | catalogued as rs781028840, COSV67410178; called by muse, mutect2, varscan2
- GRM3 | c.869G>A p.R290H | Missense Mutation (SNP) | VAF 32/203 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV64466818; called by muse, mutect2, varscan2
- LRP4 | c.1054C>T p.R352W | Missense Mutation (SNP) | VAF 69/325 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as rs148456240; called by muse, mutect2, varscan2
- OTOA | c.54T>G p.H18Q | Missense Mutation (SNP) | VAF 64/336 reads (19%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.996); catalogued as rs1319997267; called by muse, varscan2
- PDP2 | c.339G>C p.Q113H | Missense Mutation (SNP) | VAF 25/171 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.104); catalogued as COSV61240467; called by muse, mutect2, varscan2
- SPACA1 | c.130G>T p.E44* | Nonsense Mutation (SNP) | VAF 45/287 reads (16%) | catalogued as COSV52759497; called by muse, mutect2, varscan2
- ZNF729 | c.2423C>T p.S808F | Missense Mutation (SNP) | VAF 43/300 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as rs1274347324; called by muse, mutect2, varscan2
- BSG | c.1006C>A p.L336M | Missense Mutation (SNP) | VAF 70/400 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- COASY | c.815C>T p.P272L | Missense Mutation (SNP) | VAF 36/132 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- COX8A | c.115-2A>G p.X39_splice | Splice Site (SNP) | VAF 54/256 reads (21%) | called by muse, mutect2, varscan2
- DHX15 | c.770T>C p.I257T | Missense Mutation (SNP) | VAF 17/142 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); called by muse, mutect2, varscan2
- DSEL | c.857G>T p.G286V | Missense Mutation (SNP) | VAF 20/173 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAT4 | c.159A>C p.E53D | Missense Mutation (SNP) | VAF 47/257 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- FOXD4L4 | c.671C>A p.A224E | Missense Mutation (SNP) | VAF 42/814 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.403); called by muse, mutect2
- FOXO1 | c.178T>A p.S60T | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, varscan2
- IGBP1P2 | c.824A>G p.Q275R | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); called by muse, mutect2, varscan2
- IGF1R | c.2687T>A p.L896Q | Missense Mutation (SNP) | VAF 59/367 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- INHBB | c.290C>T p.A97V | Missense Mutation (SNP) | VAF 47/246 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- IQGAP2 | c.3412T>G p.L1138V | Missense Mutation (SNP) | VAF 47/326 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- JMJD1C | c.6483G>A p.W2161* | Nonsense Mutation (SNP) | VAF 11/81 reads (14%) | called by muse, mutect2
- NR2E1 | c.164G>A p.G55E | Missense Mutation (SNP) | VAF 87/473 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.406); called by muse, mutect2, varscan2
- PCDH9 | c.3647T>C p.L1216P (on ENST00000377865 / NM_203487.3; = p.L1182P on NM_020403.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/221 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- PENK | c.547A>C p.S183R | Missense Mutation (SNP) | VAF 10/258 reads (4%) | SIFT tolerated (0.5); PolyPhen benign (0.179); called by muse, mutect2
- PHLPP2 | c.2234G>T p.G745V | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- RFX1 | c.2683_2686del p.A895Rfs*21 | Frame Shift Del (DEL) | VAF 38/251 reads (15%) | called by mutect2, pindel, varscan2
- RPL30 | c.76A>G p.K26E | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- SCPEP1 | c.1193A>G p.K398R | Missense Mutation (SNP) | VAF 9/202 reads (4%) | SIFT tolerated (0.38); PolyPhen benign (0.052); called by muse, mutect2
- SESN1 | c.397T>A p.L133I (on ENST00000356644 / NM_001199933.1; = p.L192I on NM_014454.3) | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SLC10A5 | c.1176G>T p.K392N | Missense Mutation (SNP) | VAF 22/139 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SYVN1 | c.928A>T p.I310F | Missense Mutation (SNP) | VAF 33/194 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- UQCC1 | c.761A>C p.K254T | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, varscan2
- VCL | c.1450A>G p.S484G | Missense Mutation (SNP) | VAF 72/336 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- VHL | c.469_480delinsT p.T157Sfs*13 | Frame Shift Del (DEL) | VAF 64/382 reads (17%) | called by pindel, varscan2*
- CAMTA2 | c.1668T>C p.P556= | Silent (SNP) | VAF 11/86 reads (13%) | called by muse, mutect2, varscan2
- CASP12 | c.354A>G p.E118= | Silent (SNP) | VAF 11/94 reads (12%) | called by muse, mutect2, varscan2
- CLUAP1 | c.744T>C p.T248= | Silent (SNP) | VAF 19/72 reads (26%) | called by muse, mutect2, varscan2
- DDHD2 | c.81G>A p.E27= | Silent (SNP) | VAF 42/276 reads (15%) | catalogued as rs751170158; called by muse, mutect2, varscan2
- FREM2 | c.4605G>C p.V1535= | Silent (SNP) | VAF 38/294 reads (13%) | called by muse, mutect2, varscan2
- INSR | c.2037G>A p.K679= | Silent (SNP) | VAF 22/124 reads (18%) | called by muse, varscan2
- NIFK | c.804C>A p.S268= | Silent (SNP) | VAF 27/153 reads (18%) | called by muse, mutect2, varscan2
- PCDHAC2 | c.2271C>T p.Y757= | Silent (SNP) | VAF 21/149 reads (14%) | catalogued as rs1554231375, COSV99145774; called by muse, mutect2, varscan2
- ZC3H4 | c.3000G>A p.A1000= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as rs771839449, COSV53410616; called by muse, mutect2, varscan2
- AC244517.10 | c.36-8971C>T | Intron (SNP) | VAF 97/786 reads (12%) | catalogued as rs556466336; called by muse, mutect2, varscan2
- ADAM10 | c.207-9253G>A | Intron (SNP) | VAF 22/108 reads (20%) | called by muse, mutect2
- ANK3 | c.3173+580T>C | Intron (SNP) | VAF 12/71 reads (17%) | called by muse, mutect2
- DAAM2 | c.*2238T>C | 3'UTR (SNP) | VAF 41/223 reads (18%) | catalogued as rs1263790441; called by muse, mutect2, varscan2
- HNRNPA1 | c.132+50A>G | Intron (SNP) | VAF 48/231 reads (21%) | called by muse, mutect2, varscan2
- PAQR5 | c.512+1851T>C | Intron (SNP) | VAF 28/199 reads (14%) | called by muse, mutect2, varscan2
- RPL13A | c.256+88T>C | Intron (SNP) | VAF 71/375 reads (19%) | catalogued as rs745575528; called by muse, mutect2, varscan2
